Somatic mutation profile of tumor specimen TCGA-AA-A004-01A (aliquot TCGA-AA-A004-01A-01W-A00E-09) from TCGA case TCGA-AA-A004, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.5 years (27,943 days).
Specimen TCGA-AA-A004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6007cc94-9542-4fd5-b2b9-1bb221a95757.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A004-10A (Blood Derived Normal), aliquot TCGA-AA-A004-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fda8c35-8f2a-4a64-8868-830f89bee1eb

The open-access MAF lists 74 somatic variants for this specimen: 60 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, Frame Shift Del 3, In Frame Del 2, Splice Site 1, Translation Start Site 1, Intron 1, Nonsense Mutation 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV55948568; called by muse, mutect2, varscan2
- ABCB4 | c.1994A>G p.H665R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55931751; called by muse, mutect2
- ACAA1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV57179679; called by muse, mutect2
- ADAMTS5 | c.1964A>G p.K655R | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53175342; called by muse, mutect2, varscan2
- ADHFE1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV52553191; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1324C>G p.P442A | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV57278161; called by muse, mutect2, varscan2
- CACNA1C | c.1215C>T p.S405= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as rs751480224, COSV100216745; called by muse, mutect2
- CALD1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62644986; called by muse, mutect2, varscan2
- CASS4 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs756117582, COSV64385337; called by muse, mutect2, varscan2
- CCAR2 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99254498; called by muse, mutect2, varscan2
- CCSER1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776696932, COSV61404887, COSV61480749; called by muse, mutect2, varscan2
- CDH3 | c.2488T>C p.*830Qext*37 | Nonstop Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99867803; called by muse, mutect2, varscan2
- CEMIP | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as COSV54987741; called by muse, mutect2, varscan2
- CFHR5 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.636); catalogued as COSV56817732; called by muse, mutect2, varscan2
- CHD7 | c.4478G>A p.R1493H | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71106952; called by muse, mutect2, varscan2
- CHST10 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99958750; called by muse, mutect2
- DDX23 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV57281922; called by muse, mutect2
- DNAAF1 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs149659582; called by mutect2, varscan2
- DOCK1 | c.4141G>A p.A1381T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs778556643, COSV54729048; called by muse, mutect2
- FFAR2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200165905, COSV55831656; called by muse, mutect2, varscan2
- HMCN1 | c.14927G>A p.R4976Q | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201563661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL21 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs141748932; called by muse, mutect2, varscan2
- KCNN3 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as COSV55212142; called by muse, varscan2
- LBHD1 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs761768836, COSV100649029, COSV63473253; called by muse, mutect2, varscan2
- LELP1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs573106359, COSV64202277; called by muse, mutect2, varscan2
- MAN2A1 | c.1475A>T p.D492V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54846016; called by muse, mutect2, varscan2
- MDN1 | c.13855G>T p.D4619Y | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV65516829, COSV65517541; called by muse, mutect2, varscan2
- MYLK | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100659434, COSV60604248; called by muse, mutect2, varscan2
- MYO18B | c.6760G>A p.V2254M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs780958841, COSV59124688; called by muse, mutect2, varscan2
- NKG7 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52467041; called by muse, mutect2, varscan2
- OR10H5 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 132/213 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as rs746677353, COSV58277366; called by muse, mutect2, varscan2
- OR4C11 | c.892A>T p.K298* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV56352103; called by muse, mutect2, varscan2
- OR4M1 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 211/747 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV60059307; called by muse, mutect2, varscan2
- PCDH17 | c.3412G>A p.V1138I | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.956); catalogued as COSV64971502; called by muse, mutect2, varscan2
- PCDH19 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV55257171; called by muse, mutect2
- PCDHA5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1393571238, COSV65349067; called by muse, mutect2, varscan2
- PITPNC1 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as COSV55444335; called by muse, mutect2, varscan2
- PIWIL4 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371297833; called by muse, mutect2, varscan2
- PLPP3 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs1236594942, COSV64838576; called by muse, mutect2
- PPOX | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57086561; called by muse, mutect2, varscan2
- PRUNE2 | c.7771_7774del p.L2591Qfs*12 | Frame Shift Del (DEL) | VAF 42/229 reads (18%) | catalogued as rs1194973681; called by mutect2, pindel, varscan2
- PTPN18 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs772861869, COSV51557923; called by muse, mutect2, varscan2
- RBM26 | c.3011C>G p.S1004C (on ENST00000438737 / NM_001366735.2; = p.S977C on NM_022118.5) | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57390982; called by muse, mutect2, varscan2
- ROR1 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.263); catalogued as rs374512783; called by muse, mutect2, varscan2
- RPA1 | c.1309G>T p.G437W | Missense Mutation (SNP) | VAF 114/184 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54607086; called by muse, mutect2, varscan2
- SNRK | c.431_432del p.N144Sfs*5 | Frame Shift Del (DEL) | VAF 61/237 reads (26%) | catalogued as COSV56065772; called by mutect2, pindel, varscan2
- TECTA | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760011660, COSV50687716; called by muse, mutect2, varscan2
- TEX26 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66839389; called by muse, mutect2, varscan2
- TLL1 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV50261381, COSV50295756; called by muse, mutect2, varscan2
- TLR8 | c.1060C>T p.P354S (on ENST00000218032 / NM_138636.5; = p.P372S on NM_016610.4) | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.231); catalogued as COSV54316274; called by muse, mutect2, varscan2
- TRPS1 | c.3334C>T p.R1112W (on ENST00000220888 / NM_001330599.2; = p.R1125W on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374896129; called by muse, mutect2, varscan2
- UBE2G1 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs1196054003, COSV67833069; called by muse, mutect2, varscan2
- UPP2 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 65/620 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV50046287; called by muse, mutect2, varscan2
- USH2A | c.5104G>A p.V1702M | Missense Mutation (SNP) | VAF 108/452 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs201799575, COSV56324658, COSV56376540; called by muse, mutect2, varscan2
- UTP4 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as rs769413821, COSV58731985; called by muse, mutect2, varscan2
- WDR48 | c.1174-1G>A p.X392_splice | Splice Site (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100176462; called by muse, mutect2, varscan2
- ZNF415 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769109320, COSV54698902; called by muse, mutect2, varscan2
- COL14A1 | c.2644_2679del p.N882_M893del | In Frame Del (DEL) | VAF 100/388 reads (26%) | called by mutect2, pindel
- MARCHF7 | c.481_490delinsC p.S161_S164delinsR | In Frame Del (DEL) | VAF 30/51 reads (59%) | called by pindel, varscan2*
- TP53 | c.518_519del p.V173Efs*7 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- APCDD1L | c.1233C>T p.Y411= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs747130919, COSV64485268; called by muse, mutect2, varscan2
- C12orf50 | c.759G>A p.T253= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as rs776651485, COSV53893183; called by muse, mutect2, varscan2
- CHSY3 | c.1044C>T p.C348= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs373792516; called by muse, mutect2, varscan2
- CRISPLD1 | c.855C>T p.S285= | Silent (SNP) | VAF 81/545 reads (15%) | catalogued as rs375398675; called by muse, mutect2, varscan2
- CSMD3 | c.5169C>A p.V1723= (on ENST00000297405 / NM_001363185.1; = p.V1619= on NM_052900.3) | Silent (SNP) | VAF 52/417 reads (12%) | catalogued as COSV52096568; called by muse, mutect2, varscan2
- EXTL3 | c.369C>T p.N123= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs761359440, COSV55036646; called by muse, mutect2, varscan2
- GSTA2 | c.594A>G p.L198= | Silent (SNP) | VAF 78/311 reads (25%) | catalogued as COSV72414534; called by muse, mutect2, varscan2
- GZMA | c.702C>T p.C234= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs371339546; called by muse, mutect2, varscan2
- HMCN1 | c.14928G>T p.R4976= | Silent (SNP) | VAF 32/262 reads (12%) | catalogued as COSV99625803; called by muse, mutect2, varscan2
- LRFN2 | c.2139G>A p.P713= | Silent (SNP) | VAF 43/52 reads (83%) | catalogued as rs377714768; called by muse, mutect2, varscan2
- OR10AG1 | c.480C>T p.C160= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs754960387, COSV56631269; called by muse, mutect2, varscan2
- SEC24C | c.1371C>T p.P457= | Silent (SNP) | VAF 51/217 reads (24%) | catalogued as COSV59539607; called by mutect2, varscan2
- ZNF528 | c.510T>C p.A170= | Silent (SNP) | VAF 51/105 reads (49%) | catalogued as COSV64618274; called by muse, mutect2, varscan2
- S1PR3 | c.-148+278T>G | Intron (SNP) | VAF 19/43 reads (44%) | catalogued as COSV57836206; called by muse, mutect2, varscan2
